Somatic mutation profile of tumor specimen TCGA-D9-A3Z4-01A (aliquot TCGA-D9-A3Z4-01A-11D-A23B-08) from TCGA case TCGA-D9-A3Z4, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 54.1 years (19,749 days).
Specimen TCGA-D9-A3Z4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 710177b9-f801-4d84-8576-1e4c2d5ed480.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D9-A3Z4-10A (Blood Derived Normal), aliquot TCGA-D9-A3Z4-10A-01D-A23B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14155d37-424a-421c-90c1-248f9f97a31e

The open-access MAF lists 182 somatic variants for this specimen: 119 protein-altering or splice-affecting, 58 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 58, Nonsense Mutation 7, Intron 2, Splice Region 2, In Frame Del 2, Frame Shift Del 1, 3'UTR 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 194/246 reads (79%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RAG1 | c.2147G>A p.R716Q | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1064793248, COSV55025740; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACAD11 | c.327T>G p.S109R | Missense Mutation (SNP) | VAF 80/193 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV53899159; called by muse, mutect2, varscan2
- ACSM4 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs1226667107, COSV68068577; called by muse, mutect2
- ADGRB3 | c.4253G>A p.R1418Q | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1046244884, COSV53245112; called by muse, mutect2, varscan2
- ADGRV1 | c.5408C>T p.S1803F | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.969); catalogued as rs371348667, COSV67990524; called by muse, mutect2, varscan2
- ADHFE1 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 483/660 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52555998; called by muse, mutect2, varscan2
- APOBR | c.3025C>T p.R1009C (on ENST00000431282; = p.R1018C on NM_018690.4) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs528190355, COSV60489033; called by muse, mutect2, varscan2
- APP | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61001367; called by muse, mutect2, varscan2
- ATR | c.6698G>C p.S2233T | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV63386695, COSV63388891; called by muse, mutect2, varscan2
- BAMBI | c.646A>C p.M216L | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs369100188; called by muse, mutect2, varscan2
- BCAT2 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234657138, COSV100302404; called by muse, mutect2, varscan2
- BRINP1 | c.1713T>A p.H571Q | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV56306619; called by muse, mutect2, varscan2
- BSN | c.9988C>T p.R3330* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as rs866219912, COSV56523073; called by muse, mutect2, varscan2
- C2orf15 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.027); catalogued as COSV56781666, COSV56782206; called by muse, mutect2, varscan2
- CCDC141 | c.4255A>C p.T1419P | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55377975; called by muse, mutect2, varscan2
- CCDC68 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV61604220; called by muse, mutect2, varscan2
- CEACAM3 | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 133/348 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV55762441, COSV55763367; called by muse, mutect2, varscan2
- CENPF | c.5036C>T p.S1679L | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV65276904; called by muse, mutect2, varscan2
- CLCNKA | c.2057C>T p.P686L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.109); catalogued as COSV58892835; called by muse, mutect2, varscan2
- CLEC10A | c.758G>A p.G253E (on ENST00000254868 / NM_182906.4; = p.G229E on NM_006344.4) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1471199418, COSV99644704; called by muse, mutect2, varscan2
- CLEC10A | c.757G>A p.G253R (on ENST00000254868 / NM_182906.4; = p.G229R on NM_006344.4) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1337787876, COSV99644707; called by muse, mutect2, varscan2
- CNGA1 | c.1883G>A p.G628E | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV62055549; called by muse, mutect2, varscan2
- COL17A1 | c.2006C>T p.S669F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as rs1425049989, COSV62228154; called by muse, mutect2, varscan2
- COL21A1 | c.2075G>A p.G692E | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763112285, COSV55169233; called by muse, varscan2
- COL21A1 | c.2074G>T p.G692W | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99778608, COSV99778797; called by muse, varscan2
- CPT1A | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs536671702, COSV55758731; called by muse, mutect2, varscan2
- CSTL1 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as COSV55678657; called by muse, mutect2, varscan2
- CTNND2 | c.3617C>T p.P1206L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100476148; called by muse, mutect2, varscan2
- CTNND2 | c.3616C>T p.P1206S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as COSV58915994; called by muse, mutect2, varscan2
- CUL3 | c.2000C>T p.S667F | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52367493; called by muse, mutect2, varscan2
- DAOA | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as rs748474651, COSV61601558, COSV61601723; called by muse, mutect2, varscan2
- DCST1 | c.1869G>A p.P623= | Splice Region (SNP) | VAF 17/36 reads (47%) | catalogued as rs143335670; called by muse, mutect2, varscan2
- DDX3X | c.1672C>T p.L558F (on ENST00000399959; = p.L559F on NM_001356.5) | Missense Mutation (SNP) | VAF 46/54 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV67862997, COSV67864078; called by muse, mutect2, varscan2
- DDX60L | c.2992G>A p.G998R | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52717638, COSV99036209; called by muse, mutect2, varscan2
- DNAH9 | c.7909C>T p.L2637F | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as COSV52362634; called by muse, mutect2, varscan2
- EFEMP1 | c.1205C>T p.S402F | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62617040; called by muse, mutect2, varscan2
- EIF3D | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53404361; called by muse, mutect2, varscan2
- ERICH3 | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 76/101 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV58612748; called by muse, mutect2, varscan2
- FCRL5 | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 87/217 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as rs1421661212, COSV62517475; called by muse, mutect2, varscan2
- FERMT1 | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.424); catalogued as rs1161003417, COSV54095340; called by muse, mutect2, varscan2
- FGA | c.2007G>T p.L669F | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs779020384, COSV100120251, COSV57398500; called by muse, mutect2, varscan2
- FNDC1 | c.1029T>A p.D343E | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.306); catalogued as COSV51943281; called by muse, mutect2, varscan2
- GATAD2B | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV64083998; called by muse, mutect2, varscan2
- GBP2 | c.1067G>A p.R356K | Missense Mutation (SNP) | VAF 131/156 reads (84%) | SIFT tolerated (0.29); PolyPhen benign (0.101); catalogued as COSV100975386; called by muse, mutect2, varscan2
- GDAP1 | c.596A>G p.H199R | Missense Mutation (SNP) | VAF 37/321 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.627); catalogued as COSV55186447; called by muse, mutect2, varscan2
- GPLD1 | c.1633G>A p.G545R | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57756268; called by muse, mutect2, varscan2
- GRIK4 | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 82/129 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs1234274683, COSV70804710; called by muse, mutect2, varscan2
- HCLS1 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.935); catalogued as rs754450913, COSV58858486; called by muse, mutect2, varscan2
- HDAC9 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67779407; called by muse, mutect2, varscan2
- HEPHL1 | c.2292A>C p.E764D | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV59894176; called by muse, mutect2, varscan2
- HGS | c.1771A>T p.S591C | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as COSV61269254; called by muse, mutect2, varscan2
- HSD17B7 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0.018); catalogued as COSV54419132; called by muse, mutect2, varscan2
- HSPA1L | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.073); catalogued as COSV65149001; called by muse, mutect2, varscan2
- IL36G | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV52078887; called by muse, mutect2, varscan2
- KCNK5 | c.1048A>G p.N350D | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as COSV63989165; called by muse, mutect2, varscan2
- KCTD19 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.091); catalogued as rs1453783022, COSV58571586, COSV58573556; called by muse, mutect2, varscan2
- KEL | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765373517, COSV62336503; called by muse, mutect2, varscan2
- KIAA1109 | c.6304T>A p.S2102T | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52683288; called by muse, mutect2, varscan2
- KRT5 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.163); catalogued as rs373891687; called by muse, mutect2, varscan2
- LHX9 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.389); catalogued as COSV61330219; called by muse, mutect2, varscan2
- LONRF3 | c.1085C>T p.S362F (on ENST00000371628 / NM_001031855.3; = p.S321F on NM_024778.5) | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV59154889; called by muse, mutect2, varscan2
- LRRC66 | c.1061G>C p.R354T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.505); catalogued as COSV58635336; called by muse, mutect2, varscan2
- LRRTM3 | c.394G>C p.V132L | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.349); catalogued as COSV63668814; called by muse, mutect2, varscan2
- MAPT | c.1813C>T p.P605S (on ENST00000262410 / NM_001377265.1; = p.P213S on NM_005910.5) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV52243742; called by muse, mutect2, varscan2
- MEF2B | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 34/76 reads (45%) | catalogued as COSV50767522; called by muse, mutect2, varscan2
- MRTFB | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.017); catalogued as rs760038885, COSV59120962; called by muse, mutect2, varscan2
- MYOCD | c.2092C>A p.P698T | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.236); catalogued as COSV58507626; called by muse, mutect2, varscan2
- NBR1 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV57830934; called by muse, mutect2, varscan2
- NDNF | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65634201; called by muse, mutect2, varscan2
- NLRP5 | c.2422C>T p.P808S | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.38); catalogued as COSV66765874, COSV66766132; called by muse, mutect2, varscan2
- NRK | c.1457G>T p.R486M | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV54601689; called by muse, mutect2, varscan2
- NYNRIN | c.4562G>A p.G1521D | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.748); catalogued as COSV66843730; called by muse, mutect2, varscan2
- OCIAD2 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 86/227 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs768258880, COSV56717096; called by muse, mutect2, varscan2
- P4HA3 | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as rs755451827, COSV59042855; called by muse, mutect2, varscan2
- PEG3 | c.2229T>G p.S743R | Missense Mutation (SNP) | VAF 73/211 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.055); catalogued as COSV55640657; called by muse, mutect2, varscan2
- PKDREJ | c.4522C>T p.L1508F | Missense Mutation (SNP) | VAF 85/228 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0.293); catalogued as rs751447119, COSV53551017; called by muse, mutect2, varscan2
- PLIN5 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.29); catalogued as COSV67850878; called by muse, mutect2, varscan2
- PNMA2 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs368364116; called by muse, mutect2, varscan2
- PPP1R3A | c.3041T>C p.I1014T | Missense Mutation (SNP) | VAF 88/201 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV52887582; called by muse, mutect2, varscan2
- PRSS57 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 2/11 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.03); catalogued as COSV61386417; called by muse, mutect2
- PTCH2 | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.963); catalogued as COSV64712315; called by muse, mutect2, varscan2
- PYCR2 | c.538T>A p.Y180N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100661510; called by muse, mutect2, varscan2
- RALYL | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as rs772399055, COSV72822681; called by muse, mutect2, varscan2
- RFPL2 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as COSV50713647; called by muse, mutect2
- RFX6 | c.2635C>T p.P879S | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV60587204; called by muse, mutect2, varscan2
- RNF151 | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.018); catalogued as COSV58400481; called by muse, mutect2, varscan2
- ROGDI | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58928145; called by muse, mutect2, varscan2
- RPP40 | c.1025T>G p.V342G | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60292539; called by muse, mutect2, varscan2
- RPS27A | c.349C>A p.L117I | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as COSV55052812; called by muse, mutect2, varscan2
- SCUBE1 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100683616, COSV62614379; called by muse, mutect2, varscan2
- SIGLEC5 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs772906943, COSV55777922, COSV55781663; called by muse, mutect2, varscan2
- SLC15A2 | c.1546A>G p.T516A | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55197400, COSV55199341; called by muse, mutect2, varscan2
- SLC16A12 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs1287452968, COSV57950501; called by muse, mutect2, varscan2
- SMAD1 | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 53/153 reads (35%) | catalogued as COSV57472190; called by muse, mutect2, varscan2
- ST18 | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 127/199 reads (64%) | SIFT tolerated (0.76); PolyPhen benign (0.026); catalogued as COSV52484477; called by muse, mutect2, varscan2
- STX11 | c.29A>G p.D10G | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV62449781; called by muse, mutect2, varscan2
- TCHH | c.3016G>A p.E1006K | Missense Mutation (SNP) | VAF 151/401 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.118); catalogued as COSV64274807, COSV64276289; called by muse, mutect2, varscan2
- TEK | c.3281G>T p.R1094I | Missense Mutation (SNP) | VAF 38/54 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1386891182, COSV66230962; called by muse, mutect2, varscan2
- TELO2 | c.1435C>T p.Q479* | Nonsense Mutation (SNP) | VAF 20/50 reads (40%) | catalogued as COSV51979746, COSV99248214; called by muse, mutect2, varscan2
- THRA | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.717); catalogued as COSV52844786; called by muse, mutect2, varscan2
- TLL1 | c.2269C>T p.R757C | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs376797148; called by muse, mutect2, varscan2
- TRPM2 | c.4321G>A p.E1441K | Missense Mutation (SNP) | VAF 54/69 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as rs759143585, COSV55970999; called by muse, mutect2, varscan2
- TTN | c.57250G>A p.E19084K (on ENST00000591111; = p.E11660K on NM_003319.4) | Missense Mutation (SNP) | VAF 44/104 reads (42%) | PolyPhen benign (0.169); catalogued as COSV60199265; called by muse, mutect2, varscan2
- TTN | c.40945A>T p.K13649* (on ENST00000591111; = p.K6225* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 117/282 reads (41%) | catalogued as COSV60199307; called by muse, mutect2, varscan2
- TTN | c.14068G>A p.G4690S (on ENST00000591111; = p.G3763S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | PolyPhen probably damaging (0.999); catalogued as COSV60199342; called by muse, mutect2, varscan2
- TTN | c.4637C>T p.T1546I (on ENST00000591111; = p.T1500I on NM_003319.4) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | PolyPhen benign (0.067); catalogued as COSV60199354; called by muse, mutect2, varscan2
- USP29 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.871); catalogued as COSV54142908, COSV99518228; called by muse, mutect2, varscan2
- USP30 | c.730C>T p.R244* | Nonsense Mutation (SNP) | VAF 49/150 reads (33%) | catalogued as rs1309340440, COSV57448740; called by muse, mutect2, varscan2
- UTP20 | c.2212C>T p.P738S | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV55374026; called by muse, mutect2, varscan2
- VPS13A | c.8843C>T p.A2948V | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV62433761; called by muse, mutect2, varscan2
- ZC3H13 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 72/121 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); catalogued as COSV54459011; called by muse, mutect2, varscan2
- ZG16B | c.549G>A p.W183* | Nonsense Mutation (SNP) | VAF 47/115 reads (41%) | catalogued as COSV66526051; called by muse, mutect2, varscan2
- ZNF280B | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs1481090978, COSV100840129, COSV64529325; called by muse, mutect2, varscan2
- ZNF600 | c.1126C>T p.H376Y | Missense Mutation (SNP) | VAF 88/242 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57743917; called by muse, mutect2, varscan2
- CEP192 | c.3679_3681del p.P1227del | In Frame Del (DEL) | VAF 23/64 reads (36%) | called by mutect2, pindel, varscan2
- GUF1 | c.1891del p.R631Efs*3 | Frame Shift Del (DEL) | VAF 22/97 reads (23%) | called by pindel, varscan2
- MARCHF2 | c.582G>T p.L194= | Splice Region (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- TBL3 | c.598_621del p.S200_G207del | In Frame Del (DEL) | VAF 16/48 reads (33%) | called by mutect2, pindel
- ADAMTS20 | c.2751A>C p.S917= | Silent (SNP) | VAF 47/142 reads (33%) | catalogued as COSV67135296; called by muse, mutect2, varscan2
- APCDD1L | c.870G>A p.E290= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs775842759, COSV64487162; called by muse, mutect2, varscan2
- ARFGEF3 | c.1971C>T p.A657= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as rs747513186, COSV52463895; called by muse, mutect2, varscan2
- ARHGDIB | c.201C>T p.V67= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as rs781755145, COSV57456589; called by muse, mutect2, varscan2
- ASPHD1 | c.636C>T p.L212= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as rs762193171, COSV58101446; called by muse, mutect2, varscan2
- ASXL3 | c.5682C>G p.V1894= | Silent (SNP) | VAF 79/178 reads (44%) | catalogued as COSV52463450; called by muse, mutect2, varscan2
- ATP1A4 | c.2415C>T p.P805= | Silent (SNP) | VAF 134/288 reads (47%) | catalogued as COSV63627439, COSV63627909; called by muse, mutect2, varscan2
- B3GALT5 | c.267G>A p.K89= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV58199735; called by muse, mutect2, varscan2
- BACE2 | c.1203C>T p.S401= | Silent (SNP) | VAF 27/35 reads (77%) | catalogued as COSV57741462; called by muse, mutect2, varscan2
- BCAT2 | c.378G>A p.R126= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs1168576474, COSV100302403; called by muse, mutect2, varscan2
- CLCN2 | c.2355C>T p.F785= | Silent (SNP) | VAF 62/160 reads (39%) | catalogued as COSV55602813; called by muse, mutect2, varscan2
- COL1A2 | c.2679A>G p.E893= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV51962043; called by muse, mutect2, varscan2
- CXCL9 | c.324G>A p.K108= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as COSV99345744; called by muse, varscan2
- DNAH5 | c.4947C>T p.P1649= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as COSV54239701; called by muse, mutect2, varscan2
- ELF2 | c.849G>A p.Q283= (on ENST00000379550 / NM_001331036.2; = p.Q223= on NM_006874.4) | Silent (SNP) | VAF 68/159 reads (43%) | catalogued as COSV55494490; called by muse, mutect2, varscan2
- FAM47A | c.897G>A p.G299= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as COSV100649675, COSV60494233; called by muse, mutect2, varscan2
- FAM71A | c.774C>T p.S258= | Silent (SNP) | VAF 92/169 reads (54%) | catalogued as COSV54236363; called by muse, mutect2, varscan2
- FNDC1 | c.4212C>T p.D1404= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs368545994; called by muse, mutect2, varscan2
- GBA3 | c.1380C>T p.I460= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV72438423; called by muse, mutect2, varscan2
- GBP2 | c.1068G>A p.R356= | Silent (SNP) | VAF 132/157 reads (84%) | catalogued as rs1350599102, COSV100975385; called by muse, mutect2, varscan2
- GMIP | c.603G>A p.K201= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs1184260072, COSV52558298; called by muse, mutect2, varscan2
- GRM3 | c.654C>T p.S218= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV64475909; called by muse, mutect2, varscan2
- HECW1 | c.4296G>A p.T1432= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs760781754, COSV67835341; called by muse, mutect2, varscan2
- IGLV3-16 | c.96C>T p.S32= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as rs747179267; called by muse, mutect2, varscan2
- ITIH5 | c.2367C>T p.S789= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs754260167, COSV53670310; called by muse, mutect2, varscan2
- KNDC1 | c.2100C>T p.S700= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as rs764069709, COSV58842105; called by muse, mutect2, varscan2
- KRT12 | c.66C>T p.S22= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV52431722; called by muse, mutect2, varscan2
- LGI2 | c.1320C>T p.I440= | Silent (SNP) | VAF 135/321 reads (42%) | catalogued as rs374590337, COSV66122710; called by muse, mutect2, varscan2
- MED23 | c.660C>T p.S220= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV100644951, COSV63434679; called by muse, mutect2, varscan2
- MN1 | c.2970C>T p.S990= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV56556302; called by muse, mutect2, varscan2
- MNDA | c.1005G>A p.K335= | Silent (SNP) | VAF 76/210 reads (36%) | catalogued as rs372443942, COSV63741572; called by muse, mutect2, varscan2
- MYH11 | c.3513G>A p.K1171= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV55557352; called by muse, mutect2, varscan2
- NCKAP1L | c.150C>T p.S50= | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as COSV53209776; called by muse, mutect2, varscan2
- OXR1 | c.2559G>A p.G853= (on ENST00000442977 / NM_001198532.1; = p.G825= on NM_018002.3) | Silent (SNP) | VAF 50/275 reads (18%) | catalogued as COSV52426895; called by muse, mutect2, varscan2
- PAX6 | c.1095T>C p.N365= | Silent (SNP) | VAF 18/25 reads (72%) | catalogued as rs200959420, COSV53794700; called by muse, mutect2, varscan2
- PIK3CA | c.1503C>T p.S501= | Silent (SNP) | VAF 43/116 reads (37%) | catalogued as rs866406377, COSV55957016; called by muse, mutect2, varscan2
- PLOD3 | c.927G>A p.P309= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs753031028, COSV56183313; called by muse, mutect2, varscan2
- PREX1 | c.4701C>T p.I1567= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as COSV64254354; called by muse, mutect2, varscan2
- PRKCQ | c.1608G>A p.T536= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs751782966, COSV54107032; called by muse, mutect2, varscan2
- PTPDC1 | c.510C>T p.I170= (on ENST00000375360 / NM_177995.3; = p.I222= on NM_152422.4) | Silent (SNP) | VAF 45/121 reads (37%) | catalogued as COSV56624699; called by muse, mutect2, varscan2
- PUS10 | c.639C>T p.V213= | Silent (SNP) | VAF 78/185 reads (42%) | catalogued as COSV57453639; called by muse, mutect2, varscan2
- PVR | c.370C>T p.L124= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV51823981; called by muse, mutect2, varscan2
- RFX4 | c.1167G>A p.E389= (on ENST00000392842 / NM_213594.3; = p.E295= on NM_032491.6) | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV57578233; called by muse, mutect2, varscan2
- RIMS1 | c.3240G>A p.Q1080= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV53469607; called by muse, mutect2, varscan2
- RYR1 | c.6717C>T p.F2239= | Silent (SNP) | VAF 35/69 reads (51%) | catalogued as rs143102497; called by muse, mutect2, varscan2
- SERPINB7 | c.6C>T p.A2= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV60533670, COSV60534942; called by muse, mutect2, varscan2
- SLC24A3 | c.574C>T p.L192= | Silent (SNP) | VAF 58/146 reads (40%) | catalogued as COSV60125787, COSV60131917; called by muse, mutect2, varscan2
- SLC47A1 | c.204G>A p.K68= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as COSV54502642; called by muse, mutect2, varscan2
- STS | c.27C>T p.F9= | Silent (SNP) | VAF 20/27 reads (74%) | catalogued as COSV54270054; called by muse, mutect2, varscan2
- SWT1 | c.1312C>T p.L438= | Silent (SNP) | VAF 74/185 reads (40%) | catalogued as rs1304404998, COSV62257299; called by muse, mutect2, varscan2
- TDRD1 | c.1752C>T p.I584= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as COSV52593107; called by muse, mutect2, varscan2
- TTLL12 | c.1212C>T p.F404= | Silent (SNP) | VAF 51/148 reads (34%) | catalogued as COSV53356205; called by muse, mutect2, varscan2
- UNC80 | c.285C>T p.N95= | Silent (SNP) | VAF 61/139 reads (44%) | catalogued as COSV55898727; called by muse, mutect2, varscan2
- VSTM1 | c.579G>A p.R193= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV58075831; called by muse, mutect2, varscan2
- WDR43 | c.1425T>C p.F475= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV56099344; called by muse, mutect2, varscan2
- ZC3H7A | c.312C>T p.F104= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV63270494; called by muse, mutect2, varscan2
- ZNF33B | c.792C>T p.F264= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV63942959; called by muse, mutect2, varscan2
- ZNF347 | c.279T>C p.S93= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV61969860; called by muse, mutect2, varscan2
- KIF1B | c.2115+6721C>T | Intron (SNP) | VAF 59/76 reads (78%) | catalogued as rs1382537064, COSV55803233; called by muse, mutect2, varscan2
- MAGEA5 | n.295C>T | RNA (SNP) | VAF 51/65 reads (78%) | called by muse, mutect2, varscan2
- SLC26A8 | c.*1G>A | 3'UTR (SNP) | VAF 32/97 reads (33%) | catalogued as COSV100839456; called by muse, mutect2, varscan2
- TTN | c.10361-3828G>A | Intron (SNP) | VAF 46/136 reads (34%) | catalogued as COSV60447296; called by muse, mutect2, varscan2
- VSIG4 | chrX:66018915 T>C | 3'Flank (SNP) | VAF 9/11 reads (82%) | called by muse, mutect2, varscan2
